Somatic mutation profile of tumor specimen TCGA-BR-4267-01A (aliquot TCGA-BR-4267-01A-01D-1126-08) from TCGA case TCGA-BR-4267, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 51.2 years (18,699 days).
Specimen TCGA-BR-4267-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a9cb85e-3fb2-4a5a-b52f-7308f608c563.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4267-11A (Solid Tissue Normal), aliquot TCGA-BR-4267-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af03b1d6-a9b9-47d6-a339-6a31cc21b6cd

The open-access MAF lists 94 somatic variants for this specimen: 74 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 62, Silent 20, Nonsense Mutation 6, In Frame Del 3, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 21/28 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>C p.R361P | Missense Mutation (SNP) | VAF 38/58 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.409A>C p.S137R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV53909493, COSV53911078; called by muse, mutect2
- AGAP6 | c.741G>T p.E247D (on ENST00000374056 / NM_001365867.1; = p.E270D on NM_001077665.2) | Missense Mutation (SNP) | VAF 133/362 reads (37%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.965); catalogued as COSV100929103; called by muse, varscan2
- AKAP4 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 66/91 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV62074642; called by muse, mutect2, varscan2
- ALAD | c.922C>A p.R308S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV52959246, COSV52960083, COSV99474577; called by mutect2, varscan2
- B4GALNT4 | c.2575G>A p.V859I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs761726990, COSV57323710; called by muse, mutect2, varscan2
- CDH4 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.64); catalogued as rs755307987, COSV64645048, COSV64653583; called by muse, mutect2, varscan2
- CDKAL1 | c.700C>G p.P234A | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV51184292; called by muse, mutect2, varscan2
- CLIC4 | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 52/79 reads (66%) | catalogued as COSV65526149; called by muse, mutect2, varscan2
- CLK2 | c.904G>C p.D302H (on ENST00000368361 / NM_001294339.2; = p.D301H on NM_003993.4) | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV56945533; called by muse, mutect2, varscan2
- CMYA5 | c.10390A>C p.N3464H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV71406369; called by muse, mutect2, varscan2
- CPS1 | c.2989G>T p.V997F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51812346; called by muse, mutect2, varscan2
- CREB3L3 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs377239800; called by muse, mutect2, varscan2
- DCT | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs530574255, COSV65467572, COSV65469475; called by muse, mutect2, varscan2
- DMAC2 | c.690G>C p.E230D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV55728563; called by muse, mutect2, varscan2
- DNAH3 | c.9358C>T p.Q3120* | Nonsense Mutation (SNP) | VAF 80/216 reads (37%) | catalogued as rs1210965582, COSV54526322; called by muse, mutect2, varscan2
- ELF4 | c.100G>C p.A34P | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57451658, COSV57452913; called by muse, mutect2, varscan2
- ELL2 | c.152T>A p.L51* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV52983043; called by muse, mutect2, varscan2
- EPB41L1 | c.1821C>A p.S607R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99151225; called by muse, mutect2, varscan2
- EXOC3L4 | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV66295600; called by muse, mutect2, varscan2
- FBXO24 | c.821T>C p.V274A (on ENST00000241071 / NM_033506.3; = p.V312A on NM_012172.5) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV53826608; called by muse, mutect2, varscan2
- FCGRT | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55529779, COSV55531343; called by muse, mutect2
- GABRE | c.1345T>C p.W449R | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.35); PolyPhen benign (0.444); catalogued as COSV64819866; called by muse, mutect2, varscan2
- GJA9 | c.546C>G p.H182Q | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as COSV62532242; called by muse, mutect2, varscan2
- GOLGA4 | c.5371C>G p.Q1791E | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1457425451, COSV62711155; called by muse, mutect2, varscan2
- GPR37 | c.1738A>C p.S580R | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV58257217; called by muse, mutect2, varscan2
- GRIPAP1 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs1219209910, COSV100904233, COSV64552285; called by muse, mutect2, varscan2
- HRH2 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1459366736, COSV51574611; called by muse, mutect2, varscan2
- HS6ST3 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV65009962; called by muse, mutect2, varscan2
- IFIT1B | c.34G>C p.D12H | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV65663475; called by muse, mutect2, varscan2
- ITGB3 | c.614A>C p.D205A | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV71384188; called by muse, mutect2
- KCNG3 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); catalogued as COSV60149331; called by muse, mutect2, varscan2
- KIRREL1 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs913780279, COSV63287804; called by muse, mutect2, varscan2
- KMT2D | c.13675C>G p.L4559V | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56448190; called by muse, mutect2, varscan2
- MARCHF6 | c.1727A>T p.E576V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV56882124; called by muse, mutect2, varscan2
- MED23 | c.3328G>A p.V1110M | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63433050; called by muse, mutect2, varscan2
- MUC17 | c.11720C>T p.T3907I | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV60290770, COSV60299276; called by muse, mutect2, varscan2
- NEB | c.382G>C p.V128L | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as COSV51423017; called by muse, mutect2, varscan2
- NR1H3 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs182303471, COSV68008460; called by muse, mutect2, varscan2
- NUP155 | c.1066T>A p.C356S (on ENST00000231498 / NM_153485.3; = p.C297S on NM_004298.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99193794; called by muse, mutect2, varscan2
- OGFOD2 | c.923G>A p.R308Q (on ENST00000228922 / NM_001304833.1; = p.R248Q on NM_024623.3) | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54901960; called by muse, mutect2, varscan2
- OR5F1 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV53546660; called by muse, mutect2, varscan2
- PCDHB8 | c.870C>G p.S290R | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); catalogued as COSV50774487; called by muse, mutect2, varscan2
- PCSK4 | c.2187G>A p.M729I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1471525520, COSV56299521; called by muse, mutect2, varscan2
- RAB3C | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.215); catalogued as COSV51436930, COSV99276523; called by muse, mutect2, varscan2
- RNF10 | c.2236A>G p.S746G | Missense Mutation (SNP) | VAF 205/417 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV58045820; called by muse, mutect2, varscan2
- RNPEP | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55241462; called by muse, mutect2, varscan2
- RRAS | c.572G>C p.R191P | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759803129, COSV55868113, COSV55868587; called by muse, mutect2, varscan2
- RRN3 | c.1893C>A p.F631L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1394296212, COSV52214785; called by muse, mutect2, varscan2
- RTF2 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV50128835; called by muse, mutect2, varscan2
- RYR1 | c.4339G>A p.V1447M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370851779; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.1694T>A p.I565N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66793055; called by muse, varscan2
- SLC6A18 | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57251802; called by muse, mutect2, varscan2
- SLC7A4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV60384313; called by muse, mutect2, varscan2
- SPTBN4 | c.755T>A p.L252Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV58951023; called by muse, mutect2, varscan2
- SYT7 | c.217T>C p.L73= | Splice Region (SNP) | VAF 13/40 reads (33%) | catalogued as rs1421550155, COSV55656287; called by muse, mutect2, varscan2
- TESPA1 | c.1303A>T p.K435* (on ENST00000316577 / NM_001098815.3; = p.K297* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 63/208 reads (30%) | catalogued as COSV57259290; called by muse, mutect2, varscan2
- TLR7 | c.2895A>C p.E965D | Missense Mutation (SNP) | VAF 143/181 reads (79%) | SIFT tolerated (0.55); PolyPhen benign (0.348); catalogued as rs760167499, COSV66124466; called by muse, mutect2, varscan2
- TNFSF15 | c.207C>G p.F69L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV65011842; called by muse, mutect2, varscan2
- TRIM22 | c.1198A>T p.R400* | Nonsense Mutation (SNP) | VAF 29/74 reads (39%) | catalogued as COSV66091000; called by muse, mutect2, varscan2
- TRIM9 | c.1623C>G p.D541E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100031354, COSV53618312; called by muse, mutect2, varscan2
- UNC13A | c.3768G>A p.M1256I | Missense Mutation (SNP) | VAF 266/716 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1475657864, CM142661, COSV53197851; called by muse, mutect2, varscan2
- VCAN | c.10177G>C p.E3393Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54106829; called by muse, mutect2, varscan2
- ZDBF2 | c.6683C>T p.S2228L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as rs781279011, COSV65624181; called by muse, mutect2, varscan2
- ZMYM6 | c.3890A>G p.K1297R | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64121152; called by muse, mutect2, varscan2
- ZNF408 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV61238371; called by muse, mutect2, varscan2
- ZNF607 | c.997G>C p.G333R | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV67697158; called by muse, mutect2, varscan2
- ARID2 | c.1580_1580+19del p.X527_splice | Splice Site (DEL) | VAF 20/46 reads (43%) | called by mutect2, pindel, varscan2
- DOCK6 | c.2621_2623del p.Y874del | In Frame Del (DEL) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- MIPOL1 | c.1159_1206del p.A388_L403del | In Frame Del (DEL) | VAF 31/164 reads (19%) | called by mutect2, pindel
- PLXNA2 | c.1232_1264del p.Q411_G421del | In Frame Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel
- TLE4 | c.1782_1794del p.C595Afs*14 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- ACKR1 | c.816G>T p.L272= | Silent (SNP) | VAF 58/215 reads (27%) | catalogued as rs1490054367, COSV63673074; called by muse, mutect2, varscan2
- ADCY9 | c.606C>T p.G202= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV53576307; called by muse, mutect2, varscan2
- BRD7 | c.1563G>T p.L521= | Silent (SNP) | VAF 111/272 reads (41%) | catalogued as COSV54267391; called by muse, mutect2, varscan2
- CA14 | c.396A>C p.A132= | Silent (SNP) | VAF 67/175 reads (38%) | catalogued as COSV52529159; called by muse, mutect2, varscan2
- CD1C | c.342A>G p.V114= | Silent (SNP) | VAF 39/150 reads (26%) | catalogued as COSV63806626; called by muse, mutect2, varscan2
- CDHR5 | c.1956G>A p.S652= (on ENST00000358353 / NM_001171968.2; = p.S658= on NM_021924.5) | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs368338796; called by muse, mutect2, varscan2
- CDYL | c.924G>C p.V308= (on ENST00000328908 / NM_001368125.1; = p.V254= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/186 reads (31%) | catalogued as COSV59360054; called by muse, mutect2, varscan2
- CES5A | c.639C>T p.F213= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs780657709, COSV51867007; called by muse, mutect2, varscan2
- DCAF1 | c.2058C>T p.I686= | Silent (SNP) | VAF 94/233 reads (40%) | catalogued as COSV60043375, COSV60045454; called by muse, mutect2, varscan2
- FAM3B | c.178A>C p.R60= | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as COSV63613261; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.118A>C p.R40= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV63044715; called by muse, mutect2, varscan2
- GSTA5 | c.228C>G p.A76= | Silent (SNP) | VAF 54/285 reads (19%) | catalogued as COSV52862473; called by muse, mutect2, varscan2
- IDH3A | c.516C>T p.T172= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs543642336, COSV55113062; called by muse, mutect2, varscan2
- KCNG4 | c.489G>T p.R163= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV57584147; called by muse, mutect2, varscan2
- MIB1 | c.1923T>G p.L641= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV55091207; called by muse, mutect2, varscan2
- NOS1 | c.4092C>G p.L1364= | Silent (SNP) | VAF 66/263 reads (25%) | catalogued as COSV57613945; called by muse, mutect2, varscan2
- OSR2 | c.561G>A p.L187= | Silent (SNP) | VAF 61/217 reads (28%) | catalogued as COSV52557248; called by muse, mutect2, varscan2
- SLC8A2 | c.339C>T p.N113= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs779990194, COSV52640234; called by mutect2, varscan2
- TEX15 | c.6843T>A p.P2281= (on ENST00000256246; = p.P2664= on NM_001350162.2) | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV56347587; called by muse, mutect2, varscan2
- ZNF19 | c.231A>T p.A77= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV55507813, COSV55508035; called by muse, mutect2, varscan2
